Somatic mutation profile of tumor specimen TARGET-10-PARNEH-09A (aliquot TARGET-10-PARNEH-09A-01D) from TARGET case TARGET-10-PARNEH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,463 days).
Specimen TARGET-10-PARNEH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c84cd3-942d-447e-b387-2ad9134cb5cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNEH-14A (Bone Marrow Normal), aliquot TARGET-10-PARNEH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39fc164a-bc9d-4408-9419-0d83549a4e30

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDON | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV54995794; called by mutect2, varscan2
- KBTBD8 | c.1275C>A p.C425* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV55129585; called by mutect2, varscan2
- MAP4K4 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as COSV56336494; called by muse, varscan2
- EPPK1 | c.3014A>G p.E1005G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NKIRAS1 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PTDSS1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); called by muse, mutect2
- RPGRIP1 | c.1723C>A p.L575M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3F | c.1394C>A p.T465N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- ZSCAN12 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GDF6 | c.1248G>T p.P416= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- PRSS12 | c.1908T>C p.N636= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2
- RGS7 | c.1071G>A p.S357= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs751981801; ClinVar: likely benign; called by muse, varscan2
- SRPX2 | c.816C>T p.H272= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs151294854, COSV100884066; called by muse, mutect2
- TNFAIP8 | c.105C>A p.S35= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, varscan2
- UBR4 | c.5184G>T p.V1728= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100919872; called by muse, mutect2
- FAM71F1 | chr7:128714084 C>A | 5'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- SLC14A1 | c.-22+2338C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
